CCDI case PBCNSK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/40bcae06-7f19-45dc-bad6-a8cfd1e15e62

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.6 years (2,414 days).

Biospecimens (3 samples)
- Sample 0DWNR0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWNSR: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWNTM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
